OHSU case 2493 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/e8e91dd6-53d4-4722-8751-fd91de167852

Diagnoses (1)
1. Chronic neutrophilic leukemia: ICD-O-3 morphology code: 9963/3; Tissue or organ of origin: Bone marrow.

Biospecimens (1 sample)
- Sample 2722D: Tissue type: Tumor; Preservation method: Snap Frozen.
